TARGET case TARGET-10-PARDLR — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93df0584-689e-5f5f-b5fb-17dfbf5fd038

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.3 years (3,042 days); Year of diagnosis: 2007; Days to last follow up: 1,766 days (4.8 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 409 days (1.1 years); Days to first event: 409 days (1.1 years); First event: Relapse.
- Days to follow up: 1,766 days (4.8 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 18.6 ×10³/µL.
- Day 8: Bone Marrow blast count 33%; Minimal Residual Disease (Flow Cytometry) 2.6%.
- Day 15: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.033%.

Biospecimens (2 samples)
- Sample TARGET-10-PARDLR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARDLR-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARDLR-09A-01D:
- Blast %: 97

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 1766
- WBC at Diagnosis: 18.57
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 2.6
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.033
- MRD Day 29 Sensitivity: 0.001
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 33
- BMA Blasts Day 15: 1
- BMA Blasts Day 29: 0
- Karyotype: 51,XX,+5,+6,,add(9)(p21),+11,add(14)(q32),+18,+20,add(21)(p11.2)[3]/51,idem,der(6)t(1;6)(q21;q25)[8]/51,idem,der(19)t(1;19)(q21;q13.4)[4]
- Down Syndrome: No
- DNA Index: 1.11
- Alternate Therapy: Chemotherapy
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Alternate Therapy: Chemotherapy; Transplant
- Cell of Origin: B Cell ALL
